Somatic mutation profile of tumor specimen 0DUCU1 from CCDI case PBCLAF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (65 days).
Specimen 0DUCU1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31caaefb-38df-4321-bc26-97a1ceb656b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUCRK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d844e3f2-a29f-4465-8bea-2d93450f3e6f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by muse, mutect2
- PGLYRP2 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 214/605 reads (35%) | catalogued as rs1401958896; called by muse, mutect2, varscan2
- ZNF443 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs780452544, COSV56892955; called by muse, mutect2, varscan2
